Somatic mutation profile of tumor specimen TCGA-3X-AAVA-01A (aliquot TCGA-3X-AAVA-01A-11D-A417-09) from TCGA case TCGA-3X-AAVA, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 50.1 years (18,303 days).
Specimen TCGA-3X-AAVA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4134e925-4535-40c5-8702-8efa7d929284.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3X-AAVA-10A (Blood Derived Normal), aliquot TCGA-3X-AAVA-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/894f0fad-fa28-460c-85ea-f46e650e3bc0

The open-access MAF lists 41 somatic variants for this specimen: 24 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 15, Nonsense Mutation 2, In Frame Del 1, Intron 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.516G>T p.R172S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57468772, COSV57468910, COSV57481094; called by muse, mutect2, varscan2
- ACSM5 | c.1248G>C p.E416D | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as rs751142396; called by mutect2, varscan2
- ATP5PO | c.461T>A p.L154H | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs1404207036; called by muse, mutect2, varscan2
- CSMD2 | c.10345G>T p.E3449* | Nonsense Mutation (SNP) | VAF 6/13 reads (46%) | catalogued as COSV53884508; called by muse, mutect2, varscan2
- EPHA2 | c.2021A>T p.N674I | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64452045, COSV64454074; called by muse, mutect2
- IGLV3-1 | c.206A>G p.D69G | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs373029284; called by muse, mutect2, varscan2
- KLK5 | c.124G>A p.V42M | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs1172195239, COSV100307137; called by muse, mutect2
- KREMEN2 | c.381C>A p.C127* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as rs1208952056; called by muse, mutect2, varscan2
- KRT3 | c.577C>A p.Q193K | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.95); PolyPhen benign (0.014); catalogued as COSV58817647; called by muse, mutect2, varscan2
- MOV10 | c.2599_2601del p.E867del | In Frame Del (DEL) | VAF 10/33 reads (30%) | catalogued as rs1557774126; called by pindel, varscan2
- MUC16 | c.17127del p.M5710Cfs*71 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | catalogued as COSV67478823; called by mutect2, pindel*
- MUC16 | c.2161A>G p.S721G | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.188); catalogued as COSV101200767; called by muse, mutect2, varscan2
- NFE2L3 | c.1144T>C p.Y382H | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs757614557; called by muse, mutect2, varscan2
- ABCG2 | c.1500G>T p.K500N | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- ARFGAP2 | c.439C>A p.P147T | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- CAD | c.3599A>G p.N1200S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAN1A2 | c.656G>C p.G219A | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MTHFD2 | c.514A>T p.M172L | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PDGFRB | c.2519T>A p.V840D | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ROCK1 | c.190A>T p.N64Y | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- TAS2R41 | c.454A>G p.N152D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- TMEM147 | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- TUBD1 | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ZNF821 | c.709G>A p.V237M (on ENST00000425432 / NM_001376297.1; = p.V195M on NM_017530.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ASAH2 | c.777G>T p.P259= | Silent (SNP) | VAF 26/236 reads (11%) | called by muse, mutect2, varscan2
- DNAJA3 | c.1113G>T p.T371= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV99277039; called by muse, mutect2
- F8 | c.1263C>T p.P421= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs145623784, COSV64272709; called by muse, mutect2, varscan2
- GGH | c.918A>G p.G306= | Silent (SNP) | VAF 13/117 reads (11%) | catalogued as rs201429647; called by muse, mutect2, varscan2
- GPR179 | c.5727G>A p.L1909= (on ENST00000621958; = p.L1908= on NM_001004334.4) | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs1008948890; called by muse, mutect2, varscan2
- H2AC13 | c.327G>A p.L109= | Silent (SNP) | VAF 17/57 reads (30%) | called by muse, mutect2, varscan2
- LEF1 | c.252C>T p.H84= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as rs1263416005, COSV54463812; called by muse, mutect2, varscan2
- LILRB1 | c.1734G>A p.Q578= (on ENST00000427581; = p.Q528= on NM_006669.6) | Silent (SNP) | VAF 11/40 reads (28%) | called by muse, mutect2, varscan2
- PDGFRB | c.2520C>A p.V840= | Silent (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- RELB | c.900A>G p.T300= | Silent (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- RUSC2 | c.216T>A p.S72= | Silent (SNP) | VAF 6/14 reads (43%) | called by muse, varscan2
- RYR3 | c.7012C>T p.L2338= (on ENST00000389232; = p.L2339= on NM_001036.6) | Silent (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- SEMA6D | c.3189A>G p.P1063= (on ENST00000316364 / NM_153618.2; = p.P1001= on NM_020858.2) | Silent (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.1620G>A p.E540= | Silent (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- VPS54 | c.966A>G p.T322= | Silent (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- EEF1D | c.-7-3064G>A | Intron (SNP) | VAF 3/8 reads (38%) | catalogued as rs370379043; called by muse, mutect2
- TSPAN14 | chr10:80520825 A>C | 3'Flank (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
